Somatic mutation profile of tumor specimen TCGA-GN-A4U3-06A (aliquot TCGA-GN-A4U3-06A-11D-A32N-08) from TCGA case TCGA-GN-A4U3, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 37.0 years (13,524 days).
Specimen TCGA-GN-A4U3-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef31c015-61a0-444c-81ec-e4730177e18c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GN-A4U3-10F (Blood Derived Normal), aliquot TCGA-GN-A4U3-10F-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47acb3d5-1dcf-4e95-bc34-59c8a0985d10

The open-access MAF lists 379 somatic variants for this specimen: 237 protein-altering or splice-affecting, 131 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 225, Silent 131, Nonsense Mutation 7, Intron 5, RNA 4, Splice Site 2, 5'Flank 2, Frame Shift Ins 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNQ5 | c.817G>A p.G273R | Missense Mutation (SNP) | VAF 23/26 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866151724, COSV100571720; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 158/293 reads (54%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.2668G>A p.E890K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.022); catalogued as rs781249897, COSV52638284; called by muse, mutect2, varscan2
- ABCC5 | c.2068C>T p.R690C | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs758923588, COSV55587757; called by muse, mutect2, varscan2
- ABCC8 | c.4548A>T p.E1516D | Missense Mutation (SNP) | VAF 115/249 reads (46%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV100216902; called by muse, mutect2, varscan2
- ADAMTSL3 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 118/247 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774715008, COSV54469980; called by muse, mutect2, varscan2
- ADGRF3 | c.1747C>T p.L583F (on ENST00000311519 / NM_001145168.1; = p.L384F on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0.364); catalogued as COSV61050410; called by muse, mutect2, varscan2
- ADH1C | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs569012082, COSV101565169; called by muse, mutect2, varscan2
- ADNP | c.647G>T p.R216L | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV100823679; called by muse, mutect2, varscan2
- ALMS1 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 61/132 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100041768; called by muse, mutect2, varscan2
- ANK3 | c.7810G>A p.D2604N | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); catalogued as COSV55073497; called by muse, mutect2, varscan2
- ANKRD30A | c.2144G>A p.G715E (on ENST00000611781; = p.G659E on NM_052997.2) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); catalogued as COSV100653176; called by mutect2, varscan2
- ANKRD44 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs925366258, COSV56567963; called by muse, mutect2, varscan2
- ANPEP | c.2837C>T p.A946V | Missense Mutation (SNP) | VAF 52/239 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.213); catalogued as COSV100262827; called by muse, mutect2, varscan2
- APBB1IP | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.46); catalogued as rs759838553, COSV63303026; called by muse, mutect2, varscan2
- AQR | c.2371C>T p.P791S | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as COSV99333570; called by muse, mutect2, varscan2
- ARAP1 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV100501703; called by muse, varscan2
- ARHGAP28 | c.2140C>T p.R714C (on ENST00000383472 / NM_001366230.1; = p.R555C on NM_001010000.3) | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV58655431; called by muse, mutect2, varscan2
- ARHGEF5 | c.2573C>T p.S858F | Missense Mutation (SNP) | VAF 33/239 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV99282697; called by muse, mutect2, varscan2
- ASAP3 | c.248T>C p.L83S | Missense Mutation (SNP) | VAF 95/240 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV100369298; called by muse, mutect2, varscan2
- ATP13A5 | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as COSV60868223; called by muse, mutect2, varscan2
- ATP13A5 | c.422G>A p.W141* | Nonsense Mutation (SNP) | VAF 90/218 reads (41%) | catalogued as COSV100664926; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1544G>A p.G515E | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100022892; called by muse, mutect2, varscan2
- BRCA1 | c.339C>G p.N113K | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs587779367, COSV100523639, COSV58795036; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C3 | c.4318G>A p.D1440N | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs772034590, COSV99836348; called by muse, mutect2, varscan2
- CACNB4 | c.1373C>T p.S458F | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); catalogued as COSV99137929; called by muse, mutect2, varscan2
- CASD1 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 44/207 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV99802423; called by muse, mutect2, varscan2
- CCKAR | c.758G>A p.R253K | Missense Mutation (SNP) | VAF 65/118 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99810195; called by muse, mutect2, varscan2
- CD7 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs766003973, COSV99486162; called by muse, varscan2
- CDH20 | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99404819; called by muse, mutect2, varscan2
- CEP57 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs1469331147, COSV100334633; called by muse, mutect2, varscan2
- CEP85 | c.607C>T p.H203Y | Missense Mutation (SNP) | VAF 59/195 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99432003; called by muse, mutect2, varscan2
- CHL1 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs1159504136, COSV56587630; called by muse, mutect2, varscan2
- CHRNA3 | c.378T>A p.N126K | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100468070; called by muse, mutect2, varscan2
- CKAP5 | c.541C>T p.R181* | Nonsense Mutation (SNP) | VAF 43/82 reads (52%) | catalogued as COSV100370598; called by muse, mutect2, varscan2
- CLDN1 | c.382C>T p.L128F | Missense Mutation (SNP) | VAF 72/189 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as rs184529311; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNNM1 | c.1627C>T p.P543S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV100763799; called by muse, mutect2, varscan2
- CNTN6 | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1404153225, COSV100610114, COSV100610412; called by muse, mutect2, varscan2
- COL16A1 | c.3314G>A p.G1105E | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99593904; called by muse, mutect2
- COL16A1 | c.3313G>A p.G1105R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99593907, COSV99595389; called by muse, mutect2
- COL22A1 | c.2164C>T p.P722S | Missense Mutation (SNP) | VAF 74/179 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.229); catalogued as rs76179240, COSV100277287; called by muse, mutect2, varscan2
- COL6A3 | c.6334G>A p.D2112N | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV55096008, COSV99797057; called by muse, mutect2, varscan2
- COL7A1 | c.1861G>A p.V621I | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs143391124, COSV100095520; called by muse, mutect2, varscan2
- COL8A2 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as COSV57443283; called by muse, mutect2, varscan2
- COL8A2 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as rs773972659, COSV100291060; called by muse, mutect2, varscan2
- COL9A1 | c.1052C>T p.S351L | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.462); catalogued as rs201035486, COSV100296071; called by muse, mutect2, varscan2
- CPA1 | c.665A>G p.N222S | Missense Mutation (SNP) | VAF 87/166 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99163238; called by muse, mutect2, varscan2
- CPA3 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1304514609, COSV104406590, COSV56044590, COSV99936029; called by muse, mutect2, varscan2
- CPED1 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 110/222 reads (50%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.704); catalogued as rs267601251, COSV100120365; called by muse, mutect2, varscan2
- CTNND1 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 66/340 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.395); catalogued as COSV100649958; called by muse, mutect2, varscan2
- CYP4A11 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 101/181 reads (56%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.6); catalogued as rs1280460311, COSV100152255; called by muse, mutect2, varscan2
- DDX21 | c.1255C>T p.H419Y | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.76); catalogued as COSV100826498, COSV62555596; called by muse, mutect2, varscan2
- DGKZ | c.2159C>T p.P720L (on ENST00000454345 / NM_001105540.2; = p.P532L on NM_003646.4) | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100551233; called by muse, mutect2, varscan2
- DLGAP3 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.795); catalogued as COSV99332406; called by muse, mutect2, varscan2
- DLL4 | c.1673G>C p.R558P | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as COSV99989706; called by muse, mutect2, varscan2
- DLX3 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 65/170 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.348); catalogued as COSV101460533; called by muse, mutect2, varscan2
- DMBT1 | c.5485G>C p.G1829R (on ENST00000338354 / NM_001377530.1; = p.G1072R on NM_004406.3) | Missense Mutation (SNP) | VAF 69/180 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100352527, COSV100352921, COSV100353891; called by muse, mutect2, varscan2
- DNAH10 | c.4028C>T p.S1343F (on ENST00000409039; = p.S1282F on NM_207437.3) | Missense Mutation (SNP) | VAF 46/61 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1477502642, COSV101292124; called by muse, mutect2, varscan2
- DNAH6 | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs866262807, COSV52857633; called by muse, mutect2, varscan2
- DNAH8 | c.211A>T p.N71Y | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV100544071; called by muse, mutect2, varscan2
- DNM1 | c.1175T>C p.I392T | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV100359704; called by muse, mutect2, varscan2
- DOCK11 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 41/46 reads (89%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs765984589, COSV99353326; called by muse, mutect2, varscan2
- DSE | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100528450; called by muse, mutect2, varscan2
- EIF5B | c.2020C>T p.P674S | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99176950; called by muse, mutect2, varscan2
- EPB41L1 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs768666836, COSV99149600; called by muse, mutect2, varscan2
- EPB41L2 | c.2795C>T p.S932F | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759667681, COSV61353625; called by muse, mutect2, varscan2
- ERICH3 | c.3149T>C p.L1050S | Missense Mutation (SNP) | VAF 148/276 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.111); catalogued as COSV58617275; called by muse, mutect2, varscan2
- ERICH3 | c.2332G>A p.D778N | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.231); catalogued as COSV58614816; called by muse, mutect2, varscan2
- EXTL1 | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 63/131 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100959080; called by muse, mutect2, varscan2
- EZH1 | c.937C>T p.H313Y | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV70550295; called by muse, mutect2, varscan2
- F2 | c.1769G>A p.W590* | Nonsense Mutation (SNP) | VAF 59/124 reads (48%) | catalogued as COSV100319414; called by muse, varscan2
- F2 | c.1836G>A p.W612* | Nonsense Mutation (SNP) | VAF 48/116 reads (41%) | catalogued as COSV100319415; called by muse, varscan2
- FAM83B | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as COSV60926747; called by muse, mutect2, varscan2
- FAT3 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.189); catalogued as COSV53072200, COSV53124569, COSV99963822; called by muse, mutect2, varscan2
- FCER1A | c.719G>A p.R240K | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT tolerated (0.37); PolyPhen benign (0.052); catalogued as COSV100929253, COSV63668488; called by muse, mutect2, varscan2
- FCRL5 | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100708724; called by muse, mutect2, varscan2
- FLG | c.10628G>A p.S3543N | Missense Mutation (SNP) | VAF 398/704 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs1416561935, COSV64240559; called by muse, mutect2, varscan2
- FSIP2 | c.20308G>A p.E6770K | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs752276136, COSV100554562; called by muse, mutect2, varscan2
- GABRG2 | c.1394G>A p.R465Q (on ENST00000361925 / NM_001375343.1; = p.R425Q on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.411); catalogued as rs774474550, COSV100729700, COSV62715569; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GDAP1L1 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as rs772748395, COSV100697507; called by muse, varscan2
- GHR | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 90/217 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV50105823; called by muse, mutect2, varscan2
- GJA10 | c.1568G>A p.G523E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101005313; called by muse, mutect2, varscan2
- GPM6B | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 49/55 reads (89%) | SIFT tolerated (0.24); PolyPhen benign (0.131); catalogued as rs745969304, COSV57422157; called by muse, mutect2, varscan2
- GRIN2C | c.2284G>A p.A762T | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs1290577435, COSV53113644; called by muse, mutect2, varscan2
- GRM7 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100736021; called by muse, mutect2, varscan2
- GRN | c.1045C>T p.P349S | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV99274694; called by muse, mutect2, varscan2
- HEPACAM2 | c.745G>A p.D249N (on ENST00000394468 / NM_001039372.4; = p.D237N on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.889); catalogued as COSV100506453, COSV100506641, COSV100506671; called by muse, mutect2, varscan2
- HYDIN | c.10166G>A p.G3389E | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV101154037; called by muse, mutect2, varscan2
- HYDIN | c.7265G>A p.R2422K | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99992381; called by muse, mutect2, varscan2
- HYDIN | c.6883G>A p.E2295K | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.274); catalogued as COSV99992383; called by muse, mutect2, varscan2
- IGSF5 | c.156G>T p.K52N | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.824); catalogued as COSV101012015, COSV101012123; called by muse, mutect2, varscan2
- IKZF3 | c.418C>T p.H140Y | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99499396; called by muse, mutect2, varscan2
- IL20RB | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100291002; called by muse, mutect2, varscan2
- IL21R | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 41/48 reads (85%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs1343561137, COSV61972943; called by muse, mutect2, varscan2
- INSR | c.153G>T p.E51D | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV100251820, COSV57166730; called by muse, mutect2, varscan2
- ITGAM | c.1379C>T p.S460F | Missense Mutation (SNP) | VAF 75/238 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745899931, COSV99792074; called by muse, mutect2, varscan2
- KAT14 | c.1958C>T p.S653F | Missense Mutation (SNP) | VAF 96/169 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs371662156; called by muse, mutect2, varscan2
- KLC1 | c.421C>G p.L141V | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99871339; called by muse, mutect2, varscan2
- KLF4 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.301); catalogued as rs1377189236; called by muse, mutect2
- KLHL24 | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV99664810; called by muse, mutect2, varscan2
- KMT2D | c.7333C>T p.Q2445* | Nonsense Mutation (SNP) | VAF 23/60 reads (38%) | catalogued as COSV99979084; called by muse, mutect2, varscan2
- KPRP | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 111/203 reads (55%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs772281400, COSV100908681; called by muse, mutect2, varscan2
- KYNU | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV51592918, COSV99933821; called by muse, mutect2, varscan2
- LCT | c.3979G>A p.G1327S | Missense Mutation (SNP) | VAF 71/184 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99928981; called by muse, mutect2, varscan2
- LIMCH1 | c.1949G>A p.G650E | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs779145416, COSV100573634; called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs373779400; called by muse, mutect2, varscan2
- MAGEC3 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 79/94 reads (84%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as COSV100025122; called by muse, mutect2, varscan2
- MARK2 | c.1696C>T p.P566S (on ENST00000402010 / NM_001039469.2; = p.P511S on NM_004954.5) | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as COSV59284909; called by muse, mutect2, varscan2
- MGAM | c.2842G>A p.E948K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.79); PolyPhen benign (0.012); catalogued as COSV101527426; called by muse, mutect2, varscan2
- MPP7 | c.749A>G p.K250R | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.34); catalogued as rs112460703, COSV100517160; called by muse, mutect2, varscan2
- MPP7 | c.748A>G p.K250E | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV100517163; called by muse, mutect2, varscan2
- MX2 | c.1840C>T p.P614S | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100415832; called by muse, mutect2, varscan2
- MYCBPAP | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs759021550, COSV100087924; called by muse, mutect2, varscan2
- MYLK | c.4552C>T p.H1518Y | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100658610, COSV100658737; called by muse, mutect2, varscan2
- MYO16 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.884); catalogued as COSV51800237; called by muse, mutect2, varscan2
- MYO18B | c.5038G>A p.E1680K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs749666378, COSV59130355, COSV59131815; called by muse, mutect2, varscan2
- N4BP2 | c.4337C>T p.S1446F | Missense Mutation (SNP) | VAF 78/136 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV99788390; called by muse, mutect2, varscan2
- NARF | c.517C>G p.P173A | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100559619; called by muse, mutect2, varscan2
- NARF | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs751073724, COSV100559620; called by muse, mutect2, varscan2
- NEDD4L | c.1328G>A p.R443Q (on ENST00000400345 / NM_001144967.3; = p.R423Q on NM_015277.6) | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.12); catalogued as COSV99894077; called by muse, mutect2, varscan2
- NEXMIF | c.3524C>T p.S1175L | Missense Mutation (SNP) | VAF 35/39 reads (90%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as COSV99280232; called by muse, mutect2, varscan2
- NLRC5 | c.3634G>A p.E1212K | Missense Mutation (SNP) | VAF 52/82 reads (63%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as rs367666146; called by muse, mutect2, varscan2
- NLRP5 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.626); catalogued as COSV101173486; called by muse, mutect2, varscan2
- NLRP5 | c.2617C>T p.L873= | Splice Region (SNP) | VAF 37/52 reads (71%) | catalogued as COSV101173487; called by muse, mutect2, varscan2
- NOBOX | c.899A>G p.D300G | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV99779300; called by muse, mutect2, varscan2
- NOLC1 | c.1703A>C p.E568A | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV100893607; called by muse, mutect2, varscan2
- NOTCH2 | c.7124C>T p.P2375L | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.444); catalogued as COSV99863341; called by muse, mutect2, varscan2
- NRXN3 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.955); catalogued as rs543953600; called by muse, varscan2
- NUP210L | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs548145427, COSV99667588; called by muse, mutect2, varscan2
- OR10H1 | c.906G>A p.M302I | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100612397; called by muse, mutect2, varscan2
- OR10K1 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 103/353 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs527774086, COSV56870682; called by muse, mutect2
- OR1S1 | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 64/268 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58706592; called by muse, mutect2, varscan2
- OR2W3 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 80/209 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100831637, COSV64457032; called by muse, mutect2, varscan2
- OR5T2 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV57587719; called by muse, mutect2, varscan2
- OR7G1 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs555730906, COSV99528464; called by muse, varscan2
- OR7G1 | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99528465; called by muse, varscan2
- P2RY8 | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV101183970; called by muse, mutect2, varscan2
- PAPPA2 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 89/166 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as rs201904045, COSV100866672; called by muse, mutect2, varscan2
- PAX5 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100814128; called by muse, mutect2, varscan2
- PCARE | c.2189C>T p.S730F | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100527432; called by muse, mutect2, varscan2
- PCDHA9 | c.2236G>A p.G746R | Missense Mutation (SNP) | VAF 76/98 reads (78%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.366); catalogued as rs1366939358, COSV100969275; called by muse, mutect2, varscan2
- PCM1 | c.3976G>A p.E1326K | Missense Mutation (SNP) | VAF 105/177 reads (59%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs991859820, COSV100278931; called by muse, mutect2, varscan2
- PDE1C | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 134/344 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.011); catalogued as COSV100371813; called by muse, mutect2, varscan2
- PDGFRB | c.1409C>T p.S470F | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV55804568, COSV99940397; called by muse, mutect2, varscan2
- PEAR1 | c.2981C>T p.S994F | Missense Mutation (SNP) | VAF 116/214 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV99440985; called by muse, mutect2, varscan2
- PFKFB3 | c.1285G>T p.V429L | Missense Mutation (SNP) | VAF 24/64 reads (38%) | PolyPhen benign (0.005); catalogued as COSV100431858; called by muse, mutect2, varscan2
- PI4KA | c.3308C>A p.A1103D | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99745232; called by muse, mutect2, varscan2
- PKHD1L1 | c.3269C>T p.S1090F | Missense Mutation (SNP) | VAF 232/425 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV65755708; called by muse, mutect2, varscan2
- PLCB1 | c.2460G>A p.M820I | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV100570095; called by muse, mutect2, varscan2
- PLCZ1 | c.1340G>A p.G447E | Missense Mutation (SNP) | VAF 67/129 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56850728; called by muse, mutect2, varscan2
- PNPT1 | c.1112G>A p.S371N | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs538251642, COSV99569815; called by muse, mutect2, varscan2
- PPP1R3A | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.07); catalogued as rs1380388302, COSV52877979; called by muse, mutect2, varscan2
- PRB3 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 142/642 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs768625455, COSV54388919; called by muse, varscan2
- PRTG | c.3209G>A p.R1070K | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV66837284; called by muse, mutect2, varscan2
- PSD | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99192280; called by muse, mutect2, varscan2
- PSKH2 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 74/143 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99405073; called by muse, mutect2, varscan2
- RALGDS | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as rs568050976, COSV100924334; called by muse, mutect2, varscan2
- RFPL3 | c.667G>A p.G223R (on ENST00000249007 / NM_001098535.1; = p.G194R on NM_006604.2) | Missense Mutation (SNP) | VAF 73/133 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); catalogued as COSV99967002; called by muse, mutect2, varscan2
- RHAG | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 80/196 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.389); catalogued as rs868778514, COSV57704776; called by muse, mutect2, varscan2
- RIN3 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.976); catalogued as COSV99378864; called by muse, mutect2, varscan2
- RNASE10 | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.759); catalogued as rs990849965, COSV60517634; called by muse, mutect2, varscan2
- RNF144B | c.842C>A p.P281Q | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99464407; called by muse, mutect2, varscan2
- RNF17 | c.2182G>A p.V728I | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as COSV99692667; called by muse, mutect2, varscan2
- RTN4IP1 | c.29G>A p.R10K | Missense Mutation (SNP) | VAF 40/47 reads (85%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1023103707, COSV100945205; called by muse, mutect2, varscan2
- RUFY4 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as rs866517808, COSV100723138; called by muse, mutect2
- SCN10A | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 74/159 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs767815241, COSV101479306; called by muse, mutect2, varscan2
- SCTR | c.631C>T p.H211Y | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0.017); catalogued as rs1382794000, COSV99191541; called by muse, mutect2, varscan2
- SDK1 | c.4844G>A p.R1615K | Missense Mutation (SNP) | VAF 88/618 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV101269025; called by muse, mutect2, varscan2
- SDK1 | c.5014C>T p.R1672C | Missense Mutation (SNP) | VAF 76/486 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs777981406, COSV67380390; called by muse, mutect2, varscan2
- SDK1 | c.5512G>A p.V1838M | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); catalogued as COSV101269026; called by muse, mutect2, varscan2
- SELL | c.728G>A p.G243E (on ENST00000650983; = p.G230E on NM_000655.5) | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52552756; called by muse, mutect2, varscan2
- SELL | c.727G>A p.G243R (on ENST00000650983; = p.G230R on NM_000655.5) | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1194333307, COSV52555285; called by muse, mutect2, varscan2
- SERPINB10 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV53074296, COSV53074792; called by muse, mutect2, varscan2
- SETMAR | c.392G>A p.R131K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs750562265, COSV100740848; called by muse, mutect2, varscan2
- SFTPD | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV100954504; called by muse, mutect2, varscan2
- SH2D3A | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99837880; called by muse, mutect2, varscan2
- SI | c.374-1G>A p.X125_splice | Splice Site (SNP) | VAF 34/143 reads (24%) | catalogued as COSV100017282, COSV52265183; called by muse, mutect2, varscan2
- SLC25A21 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs997068435, COSV58718117; called by muse, mutect2, varscan2
- SLC34A2 | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1313059606, COSV101158259; called by muse, mutect2, varscan2
- SLC39A10 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100660563; called by muse, mutect2, varscan2
- SLC6A11 | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 88/184 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99594272; called by muse, mutect2, varscan2
- SLC9B2 | c.1117C>T p.L373F | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100293923; called by muse, mutect2, varscan2
- SLCO1B3 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1424569586, COSV53941099, COSV99681138; called by muse, mutect2, varscan2
- SLIT2 | c.2477C>T p.S826F | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1449559841, COSV56558335; called by muse, mutect2, varscan2
- SMAD9 | c.1243C>T p.R415W (on ENST00000379826 / NM_001127217.3; = p.R378W on NM_005905.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs863223772, COSV63207064; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPACA3 | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV52192471; called by muse, mutect2, varscan2
- SPDYA | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 70/138 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.409); catalogued as COSV100477899; called by muse, mutect2, varscan2
- SPTBN1 | c.1065-1G>A p.X355_splice | Splice Site (SNP) | VAF 31/84 reads (37%) | catalogued as COSV100442115; called by muse, mutect2, varscan2
- STAG3 | c.2546C>T p.P849L | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.103); catalogued as rs372921469; called by muse, mutect2, varscan2
- STAM | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 43/75 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs781891079, COSV101092218; called by muse, mutect2, varscan2
- TBCK | c.599G>T p.G200V (on ENST00000273980 / NM_001163436.4; = p.G137V on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.696); catalogued as COSV99912300; called by muse, mutect2, varscan2
- TBX4 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 89/206 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99540028; called by muse, mutect2, varscan2
- TCF7L2 | c.701C>T p.P234L (on ENST00000355995 / NM_001367943.1; = p.P211L on NM_030756.5) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.183); catalogued as rs1465566182, COSV53352252; called by muse, mutect2, varscan2
- TDRD3 | c.1244G>A p.G415E | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as rs1047439283, COSV99539985; called by muse, mutect2, varscan2
- TGFBR3 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99282671; called by muse, mutect2, varscan2
- TMC5 | c.2081T>A p.L694H (on ENST00000396229 / NM_001105248.1; = p.L448H on NM_024780.5) | Missense Mutation (SNP) | VAF 96/178 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99572297; called by muse, mutect2, varscan2
- TMEM128 | c.440C>T p.P147L (on ENST00000382753 / NM_001297552.2; = p.P123L on NM_032927.3) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99631999; called by muse, mutect2, varscan2
- TMEM63C | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as rs774355700, COSV100029305; called by muse, mutect2, varscan2
- TNFRSF13B | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT tolerated (0.22); PolyPhen benign (0.377); catalogued as rs770198071, COSV99891377; called by muse, mutect2, varscan2
- TNXB | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV100926075; called by muse, mutect2, varscan2
- TP53 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 50/55 reads (91%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as rs922736614, COSV52696702, COSV52713465, COSV99391410; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRANK1 | c.3141G>A p.W1047* | Nonsense Mutation (SNP) | VAF 30/49 reads (61%) | catalogued as COSV100082177; called by muse, mutect2, varscan2
- TRIM22 | c.1493C>T p.S498F | Missense Mutation (SNP) | VAF 59/118 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101181267; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1016G>A p.R339K | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV100708962; called by muse, mutect2, varscan2
- TRMO | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100908867; called by muse, mutect2, varscan2
- TRNT1 | c.1193T>A p.I398N | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV99214109; called by muse, mutect2, varscan2
- TSC2 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 59/93 reads (63%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV54775966; called by muse, mutect2, varscan2
- TSPAN12 | c.104T>C p.M35T | Missense Mutation (SNP) | VAF 74/136 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs774348767, COSV99763085; called by muse, mutect2, varscan2
- TTBK2 | c.1571C>T p.P524L | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs868814760, COSV99141229; called by muse, mutect2, varscan2
- TTN | c.35491C>T p.P11831S (on ENST00000591111; = p.P10904S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | PolyPhen benign (0); catalogued as COSV100602152, COSV59960609; called by muse, mutect2, varscan2
- TTN | c.17360C>T p.P5787L (on ENST00000591111; = p.P4860L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | PolyPhen benign (0.01); catalogued as COSV100602153; called by muse, mutect2, varscan2
- TTN | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 80/214 reads (37%) | PolyPhen benign (0.275); catalogued as COSV59939250; called by muse, mutect2, varscan2
- UGT1A3 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 92/184 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs143192251; called by muse, mutect2, varscan2
- USH1C | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV99139633; called by muse, mutect2, varscan2
- USP11 | c.430C>G p.R144G (on ENST00000218348; = p.R101G on NM_001371072.1) | Missense Mutation (SNP) | VAF 19/19 reads (100%) | SIFT tolerated (0.37); PolyPhen benign (0.165); catalogued as COSV54473316, COSV99510809; called by muse, mutect2, varscan2
- VIT | c.427G>A p.G143S | Missense Mutation (SNP) | VAF 98/224 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.728); catalogued as COSV101007272; called by muse, mutect2, varscan2
- VPS26C | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99898381; called by muse, mutect2, varscan2
- VPS41 | c.1164T>A p.N388K | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV100053753; called by muse, mutect2, varscan2
- WDSUB1 | c.1393A>T p.M465L | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.869); catalogued as COSV99713400; called by muse, mutect2, varscan2
- WWC3 | c.1343C>T p.S448F | Missense Mutation (SNP) | VAF 50/60 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101081230; called by muse, mutect2, varscan2
- YLPM1 | c.2654C>T p.S885F | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.323); catalogued as COSV99459113; called by muse, mutect2, varscan2
- ZBED9 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as COSV101509088, COSV101509447, COSV71729472; called by muse, mutect2, varscan2
- ZDHHC23 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746811768, COSV100362084; called by muse, mutect2, varscan2
- ZNF324 | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1185404847, COSV52180757; called by muse, mutect2, varscan2
- ZNF324B | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.166); catalogued as rs748944745, COSV100351569; called by muse, mutect2, varscan2
- ZNF385D | c.1180C>A p.P394T | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV99874038; called by muse, mutect2, varscan2
- ZNF619 | c.1253G>A p.G418E | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as COSV100123122; called by muse, mutect2, varscan2
- ZNF681 | c.129G>T p.L43F | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68076099; called by muse, mutect2, varscan2
- ZNF831 | c.2815C>T p.P939S | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100925911; called by muse, mutect2, varscan2
- ZNF831 | c.2816C>T p.P939L | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV100925912; called by muse, mutect2, varscan2
- ZNHIT2 | c.650A>G p.N217S | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs758944868, COSV99659279; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1915G>A p.G639R | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- ARHGEF3 | c.437dup p.A147Gfs*4 | Frame Shift Ins (INS) | VAF 16/86 reads (19%) | called by mutect2, pindel
- DOLK | c.179_193del p.W60_Q65delins* | Nonsense Mutation (DEL) | VAF 13/62 reads (21%) | called by mutect2, pindel, varscan2
- RBP3 | c.1754C>T p.P585L | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- TRAV9-2 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- YLPM1 | c.4519_4520del p.P1507Afs*6 | Frame Shift Del (DEL) | VAF 10/61 reads (16%) | called by mutect2, varscan2*
- ACSL5 | c.189C>T p.N63= (on ENST00000354273; = p.N119= on NM_016234.3) | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as COSV100634540; called by muse, mutect2, varscan2
- ADAM28 | c.1272G>A p.G424= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as rs377763144; called by muse, mutect2, varscan2
- ADAMTS10 | c.24C>T p.L8= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as rs1555742491, COSV99546684; called by muse, mutect2, varscan2
- ADGRL3 | c.2958C>T p.I986= (on ENST00000506720 / NM_001322402.2; = p.I918= on NM_015236.6) | Silent (SNP) | VAF 112/421 reads (27%) | catalogued as rs570445279, COSV101546953, COSV72232107; called by muse, mutect2, varscan2
- ADH7 | c.649C>T p.L217= | Silent (SNP) | VAF 70/108 reads (65%) | catalogued as rs1326048877, COSV52923069; called by muse, mutect2, varscan2
- ANAPC2 | c.720C>T p.F240= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as COSV100118966; called by muse, mutect2, varscan2
- ANK2 | c.936C>T p.D312= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV52181971; called by muse, mutect2, varscan2
- ANO2 | c.1764C>T p.V588= (on ENST00000356134 / NM_001278597.3; = p.V592= on NM_001278596.3) | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV100500253; called by muse, mutect2, varscan2
- ANO2 | c.676C>T p.L226= (on ENST00000356134 / NM_001278597.3; = p.L230= on NM_001278596.3) | Silent (SNP) | VAF 49/93 reads (53%) | catalogued as COSV100500254; called by muse, mutect2, varscan2
- AP3B2 | c.3163C>T p.L1055= (on ENST00000261722; = p.L1049= on NM_004644.5) | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV55609309, COSV99916216; called by muse, mutect2, varscan2
- ARHGAP31 | c.3489G>A p.Q1163= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV99956827; called by mutect2, varscan2
- B4GALNT4 | c.414G>A p.R138= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV100327336; called by muse, mutect2, varscan2
- BANF1 | c.222C>T p.S74= | Silent (SNP) | VAF 61/112 reads (54%) | catalogued as COSV100381365; called by muse, mutect2, varscan2
- BBS12 | c.1035G>A p.V345= | Silent (SNP) | VAF 37/55 reads (67%) | catalogued as COSV100044872; called by muse, mutect2, varscan2
- C11orf53 | c.804C>T p.S268= | Silent (SNP) | VAF 65/71 reads (92%) | catalogued as COSV54720952; called by muse, mutect2, varscan2
- C12orf42 | c.426G>A p.L142= | Silent (SNP) | VAF 29/32 reads (91%) | catalogued as rs1408948749, COSV59380754; called by muse, mutect2, varscan2
- CACNA1S | c.5184G>A p.Q1728= | Silent (SNP) | VAF 19/128 reads (15%) | catalogued as COSV100754825; called by muse, mutect2, varscan2
- CACNG5 | c.477G>A p.E159= | Silent (SNP) | VAF 35/133 reads (26%) | catalogued as COSV99400444; called by muse, mutect2, varscan2
- CCDC60 | c.399C>T p.F133= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV100554860; called by muse, mutect2, varscan2
- CEBPE | c.195G>A p.E65= | Silent (SNP) | VAF 56/109 reads (51%) | catalogued as rs758325030, COSV99247429; called by muse, mutect2, varscan2
- CFAP69 | c.1458C>T p.L486= | Silent (SNP) | VAF 42/82 reads (51%) | catalogued as COSV100289931; called by muse, mutect2, varscan2
- CMYA5 | c.6534C>T p.F2178= | Silent (SNP) | VAF 45/50 reads (90%) | catalogued as COSV101483961; called by muse, mutect2, varscan2
- COL12A1 | c.2358G>A p.T786= | Silent (SNP) | VAF 205/254 reads (81%) | catalogued as rs369803330; called by muse, mutect2, varscan2
- CPTP | c.513C>T p.F171= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as rs1039793373, COSV100028137; called by muse, mutect2, varscan2
- CRP | c.372C>T p.I124= | Silent (SNP) | VAF 226/411 reads (55%) | catalogued as rs753294711, COSV54812508; called by muse, mutect2, varscan2
- CRY2 | c.609G>A p.E203= | Silent (SNP) | VAF 42/81 reads (52%) | catalogued as COSV101314568; called by muse, mutect2, varscan2
- CTNND1 | c.810G>A p.V270= | Silent (SNP) | VAF 67/345 reads (19%) | catalogued as COSV100649957; called by muse, mutect2, varscan2
- CTNND2 | c.225C>T p.I75= | Silent (SNP) | VAF 28/37 reads (76%) | catalogued as COSV58869893; called by muse, mutect2, varscan2
- CYTIP | c.867G>A p.E289= | Silent (SNP) | VAF 73/145 reads (50%) | catalogued as rs761588156, COSV99938686; called by muse, mutect2, varscan2
- DEDD | c.762C>T p.T254= | Silent (SNP) | VAF 102/208 reads (49%) | catalogued as rs1343229919, COSV63502204, COSV63503020; called by muse, mutect2, varscan2
- DIRAS2 | c.564G>A p.R188= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs551867271, COSV101005826; called by muse, mutect2, varscan2
- DSE | c.462C>T p.S154= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV59062672; called by muse, mutect2, varscan2
- EPG5 | c.6201G>A p.Q2067= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV56347545, COSV99956844; called by muse, mutect2, varscan2
- F10 | c.1374C>T p.F458= | Silent (SNP) | VAF 31/144 reads (22%) | catalogued as COSV65021501; called by muse, mutect2, varscan2
- F11 | c.687C>T p.I229= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as rs150644991; called by muse, mutect2, varscan2
- FAM47A | c.1824C>T p.L608= | Silent (SNP) | VAF 40/45 reads (89%) | catalogued as COSV60500098; called by muse, mutect2, varscan2
- FAM83H | c.1476C>T p.G492= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV101186947; called by muse, mutect2
- FBXO40 | c.1464C>T p.F488= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as COSV57522790; called by muse, mutect2, varscan2
- FBXO47 | c.660G>A p.R220= | Silent (SNP) | VAF 44/101 reads (44%) | catalogued as rs763771483, COSV100960618, COSV100960922; called by muse, mutect2, varscan2
- GLB1L2 | c.381C>T p.I127= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs371622365; called by muse, mutect2, varscan2
- GLB1L3 | c.459C>T p.I153= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as rs370580830; called by muse, mutect2, varscan2
- GYPA | c.318G>A p.T106= | Silent (SNP) | VAF 72/144 reads (50%) | catalogued as rs749616078, COSV51618752, COSV51626553, COSV99301501; called by muse, varscan2
- HEPACAM2 | c.912G>A p.E304= (on ENST00000394468 / NM_001039372.4; = p.E292= on NM_198151.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/122 reads (18%) | catalogued as COSV100506441; called by muse, mutect2, varscan2
- HIP1 | c.2571C>T p.S857= | Silent (SNP) | VAF 83/188 reads (44%) | catalogued as rs782010743, COSV100417223; called by muse, mutect2, varscan2
- HLA-DQA2 | c.87C>T p.D29= | Silent (SNP) | VAF 87/204 reads (43%) | catalogued as COSV100890690, COSV100890783; called by muse, mutect2, varscan2
- IMPACT | c.879C>T p.N293= | Silent (SNP) | VAF 27/119 reads (23%) | catalogued as COSV99408802; called by muse, mutect2, varscan2
- INTS1 | c.5167C>T p.L1723= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs1490435800, COSV101247657; called by muse, mutect2
- IQSEC2 | c.2961C>T p.P987= (on ENST00000642864 / NM_001111125.3; = p.P782= on NM_015075.2) | Silent (SNP) | VAF 31/31 reads (100%) | catalogued as COSV100944793; called by muse, mutect2, varscan2
- ITGA5 | c.2662C>T p.L888= | Silent (SNP) | VAF 50/123 reads (41%) | catalogued as COSV99516477; called by muse, mutect2, varscan2
- ITGAE | c.1908C>T p.S636= | Silent (SNP) | VAF 27/37 reads (73%) | catalogued as COSV99560702; called by muse, mutect2, varscan2
- ITGAM | c.1380C>T p.S460= | Silent (SNP) | VAF 79/242 reads (33%) | catalogued as COSV54944290; called by muse, mutect2, varscan2
- KANK1 | c.3222T>C p.P1074= | Silent (SNP) | VAF 44/95 reads (46%) | catalogued as COSV100619572; called by muse, mutect2, varscan2
- KCNB2 | c.2103G>A p.K701= | Silent (SNP) | VAF 35/186 reads (19%) | catalogued as COSV101578715; called by muse, mutect2, varscan2
- KIAA0319 | c.135C>T p.I45= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as COSV100985371; called by muse, mutect2, varscan2
- KIF2B | c.810C>T p.F270= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV52127534; called by muse, mutect2, varscan2
- KLK4 | c.631C>T p.L211= | Silent (SNP) | VAF 54/89 reads (61%) | catalogued as rs558667514, COSV100133582; called by muse, mutect2, varscan2
- LAIR1 | c.837C>T p.I279= | Silent (SNP) | VAF 45/194 reads (23%) | catalogued as COSV100479541; called by muse, mutect2, varscan2
- LCT | c.3864G>A p.R1288= | Silent (SNP) | VAF 139/343 reads (41%) | catalogued as COSV99928983; called by muse, mutect2, varscan2
- LHFPL5 | c.297C>T p.F99= | Silent (SNP) | VAF 102/225 reads (45%) | catalogued as COSV64178703; called by muse, mutect2, varscan2
- LILRA4 | c.255C>T p.I85= | Silent (SNP) | VAF 98/160 reads (61%) | catalogued as rs994803708, COSV52493878; called by muse, mutect2, varscan2
- LILRA5 | c.180G>A p.G60= | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as rs184164219, COSV56642847; called by muse, mutect2, varscan2
- LRRC37A3 | c.159C>T p.P53= | Silent (SNP) | VAF 37/159 reads (23%) | catalogued as COSV100140954; called by muse, mutect2, varscan2
- LTBP1 | c.1302C>T p.V434= (on ENST00000404816 / NM_206943.4; = p.V108= on NM_000627.4) | Silent (SNP) | VAF 41/79 reads (52%) | catalogued as rs113801394, COSV100616719, COSV100617785; called by muse, mutect2, varscan2
- LYZL1 | c.582C>T p.S194= (on ENST00000375500; = p.S148= on NM_032517.6) | Silent (SNP) | VAF 67/148 reads (45%) | catalogued as COSV100973616; called by muse, mutect2, varscan2
- MAGEB6B | c.129C>T p.S43= | Silent (SNP) | VAF 86/89 reads (97%) | catalogued as rs774636358; called by muse, mutect2, varscan2
- MGAM | c.5286G>A p.G1762= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs745786997, COSV72073721, COSV72075224; called by muse, mutect2, varscan2
- MROH7 | c.1431C>T p.S477= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as rs769296346, COSV59873771; called by muse, mutect2, varscan2
- MUC5AC | c.14262C>T p.S4754= | Silent (SNP) | VAF 116/215 reads (54%) | catalogued as rs781047412, COSV100611381; called by muse, mutect2, varscan2
- MYD88 | c.595C>T p.L199= | Silent (SNP) | VAF 34/184 reads (18%) | catalogued as COSV100085958; called by muse, mutect2, varscan2
- MYOM2 | c.996C>T p.F332= | Silent (SNP) | VAF 24/126 reads (19%) | catalogued as COSV50704141; called by muse, mutect2, varscan2
- MYRF | c.216C>T p.V72= (on ENST00000278836 / NM_001127392.3; = p.V63= on NM_013279.4) | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV99606790; called by muse, mutect2, varscan2
- NCKAP5 | c.3903C>T p.I1301= | Silent (SNP) | VAF 64/135 reads (47%) | catalogued as COSV58475724; called by muse, mutect2, varscan2
- NDUFB2 | c.144C>T p.P48= | Silent (SNP) | VAF 154/234 reads (66%) | catalogued as COSV99199966; called by muse, mutect2, varscan2
- NRXN1 | c.3225G>A p.Q1075= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as COSV100454138; called by muse, mutect2, varscan2
- NUP210L | c.864C>T p.P288= | Silent (SNP) | VAF 45/97 reads (46%) | catalogued as COSV99667585; called by muse, mutect2, varscan2
- OPRK1 | c.210C>T p.F70= | Silent (SNP) | VAF 45/80 reads (56%) | catalogued as rs1030281216, COSV55571483; called by muse, mutect2, varscan2
- OR10G2 | c.48C>T p.F16= | Silent (SNP) | VAF 31/134 reads (23%) | catalogued as COSV73390299; called by muse, mutect2, varscan2
- OR10K1 | c.546C>A p.S182= | Silent (SNP) | VAF 102/357 reads (29%) | catalogued as COSV99193364; called by muse, mutect2
- OR2M3 | c.84C>T p.F28= | Silent (SNP) | VAF 306/565 reads (54%) | catalogued as COSV101513409; called by muse, mutect2, varscan2
- OR4D1 | c.468C>T p.S156= | Silent (SNP) | VAF 54/118 reads (46%) | catalogued as COSV99274088; called by muse, mutect2, varscan2
- OR4K15 | c.1032C>T p.F344= (on ENST00000305051; = p.F320= on NM_001005486.1) | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV100521008; called by muse, mutect2, varscan2
- OR5K4 | c.624C>T p.I208= | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as COSV61583740, COSV61583949; called by muse, mutect2, varscan2
- OR6N2 | c.135C>T p.I45= | Silent (SNP) | VAF 44/270 reads (16%) | catalogued as COSV100210029, COSV59412146; called by muse, mutect2, varscan2
- OTOL1 | c.1176C>T p.Y392= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs373418758; called by muse, mutect2, varscan2
- PADI3 | c.1782G>A p.G594= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV100968443; called by muse, mutect2, varscan2
- PAPSS2 | c.1497C>T p.S499= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV100753472; called by muse, mutect2, varscan2
- PBLD | c.550C>T p.L184= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as rs768930553, COSV99516043; called by muse, mutect2, varscan2
- PCARE | c.1410C>T p.S470= | Silent (SNP) | VAF 35/152 reads (23%) | catalogued as rs1301061213, COSV100527433; called by muse, mutect2, varscan2
- PCDHA2 | c.1473C>T p.S491= | Silent (SNP) | VAF 85/97 reads (88%) | catalogued as rs1211584292, COSV100973722; called by muse, mutect2, varscan2
- PCDHA9 | c.2235G>A p.V745= | Silent (SNP) | VAF 78/100 reads (78%) | catalogued as rs1439103901, COSV100969274; called by muse, mutect2, varscan2
- PCOLCE2 | c.516C>T p.D172= | Silent (SNP) | VAF 28/113 reads (25%) | catalogued as COSV99930506; called by muse, mutect2, varscan2
- PDP1 | c.177G>A p.K59= | Silent (SNP) | VAF 45/127 reads (35%) | catalogued as COSV99892149; called by muse, mutect2, varscan2
- PHACTR4 | c.430C>A p.R144= (on ENST00000373839 / NM_001350159.2; = p.R154= on NM_023923.4) | Silent (SNP) | VAF 37/131 reads (28%) | catalogued as COSV100868421, COSV65783914; called by muse, mutect2, varscan2
- PKHD1L1 | c.2403G>A p.T801= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as rs267601713, COSV65736382; called by muse, mutect2, varscan2
- PLEC | c.5973C>T p.I1991= (on ENST00000322810 / NM_201380.4; = p.I1881= on NM_000445.5) | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as rs782000075, COSV59638901; called by muse, mutect2, varscan2
- POM121L12 | c.468G>A p.Q156= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as rs999710286, COSV68693431; called by muse, mutect2, varscan2
- PPM1G | c.645C>T p.S215= | Silent (SNP) | VAF 58/118 reads (49%) | catalogued as COSV100084999; called by muse, mutect2, varscan2
- PRR12 | c.1674C>T p.S558= (on ENST00000615927; = p.S1379= on NM_020719.3) | Silent (SNP) | VAF 48/133 reads (36%) | catalogued as rs1414489440, COSV101330603; called by muse, mutect2, varscan2
- PTPRT | c.2895G>A p.Q965= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as COSV100626188; called by muse, mutect2, varscan2
- PYGB | c.981C>T p.F327= | Silent (SNP) | VAF 33/130 reads (25%) | catalogued as rs139728214, COSV53821952; called by muse, mutect2, varscan2
- RAPGEF4 | c.813C>T p.L271= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as COSV99910208; called by muse, mutect2, varscan2
- RIMS3 | c.273C>T p.I91= | Silent (SNP) | VAF 35/116 reads (30%) | catalogued as rs767146264, COSV101013333; called by muse, mutect2, varscan2
- RSPH9 | c.474C>T p.A158= | Silent (SNP) | VAF 183/428 reads (43%) | catalogued as COSV100937781; called by muse, mutect2, varscan2
- RYR2 | c.12249C>T p.F4083= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs371599450, COSV63678771; ClinVar: likely benign; called by muse, mutect2, varscan2
- SALL1 | c.2163G>A p.L721= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as COSV51757350; called by muse, mutect2, varscan2
- SCN1A | c.3009T>A p.T1003= (on ENST00000303395 / NM_001202435.3; = p.T992= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV100319829; called by muse, mutect2, varscan2
- SCN3A | c.4687C>T p.L1563= | Silent (SNP) | VAF 59/109 reads (54%) | catalogued as rs546233926, COSV99326257; called by muse, mutect2, varscan2
- SDHA | c.123G>A p.K41= | Silent (SNP) | VAF 51/61 reads (84%) | catalogued as rs1553997185, COSV99371414; ClinVar: likely benign; called by muse, mutect2, varscan2
- SERPINB3 | c.54G>A p.Q18= | Silent (SNP) | VAF 106/276 reads (38%) | catalogued as COSV99379693; called by muse, mutect2, varscan2
- SLC27A2 | c.1341G>A p.K447= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV51060271, COSV99982842; called by muse, mutect2, varscan2
- SLC6A12 | c.237C>T p.F79= | Silent (SNP) | VAF 31/58 reads (53%) | catalogued as rs1184197583, COSV100675030; called by muse, mutect2, varscan2
- SPATA31E1 | c.1365C>T p.V455= | Silent (SNP) | VAF 86/208 reads (41%) | catalogued as COSV57791018; called by muse, mutect2, varscan2
- SPP1 | c.438C>T p.F146= (on ENST00000395080 / NM_001040058.2; = p.F132= on NM_000582.2) | Silent (SNP) | VAF 43/119 reads (36%) | catalogued as COSV99420954; called by muse, mutect2, varscan2
- STAT3 | c.1056G>T p.L352= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV99232609; called by muse, mutect2, varscan2
- SYMPK | c.2005C>T p.L669= | Silent (SNP) | VAF 60/195 reads (31%) | catalogued as COSV99841523; called by muse, mutect2, varscan2
- TBC1D4 | c.2124C>T p.F708= | Silent (SNP) | VAF 46/105 reads (44%) | catalogued as COSV100884560; called by muse, mutect2, varscan2
- TLR4 | c.27G>A p.G9= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV100790626; called by muse, mutect2, varscan2
- TMEM270 | c.699C>T p.P233= | Silent (SNP) | VAF 141/321 reads (44%) | catalogued as COSV100260313; called by muse, mutect2, varscan2
- TPRX1 | c.141C>A p.V47= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV100445584; called by muse, mutect2, varscan2
- TRIM22 | c.1494C>T p.S498= | Silent (SNP) | VAF 59/119 reads (50%) | catalogued as COSV101181268; called by muse, mutect2, varscan2
- TSHZ3 | c.3096C>T p.S1032= | Silent (SNP) | VAF 28/42 reads (67%) | catalogued as COSV99551043; called by muse, mutect2, varscan2
- TTLL10 | c.1038C>T p.P346= (on ENST00000379289 / NM_001130045.2; = p.P273= on NM_153254.3) | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV101016526; called by muse, mutect2, varscan2
- TTN | c.4374C>T p.V1458= (on ENST00000591111; = p.V1412= on NM_003319.4) | Silent (SNP) | VAF 42/106 reads (40%) | catalogued as COSV100602154, COSV100617593; called by muse, mutect2, varscan2
- VPS8 | c.4248C>T p.F1416= (on ENST00000625842 / NM_001349294.1; = p.F1414= on NM_015303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/94 reads (44%) | catalogued as rs776853029, COSV54992812; called by muse, mutect2, varscan2
- ZNF287 | c.549C>T p.D183= | Silent (SNP) | VAF 59/61 reads (97%) | catalogued as rs751627450, COSV101209351; called by muse, mutect2, varscan2
- ZNF445 | c.690C>T p.L230= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV101253714; called by muse, mutect2
- ZNF646 | c.522G>A p.L174= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV100336520; called by muse, mutect2, varscan2
- ZNF695 | c.375G>A p.R125= | Silent (SNP) | VAF 229/418 reads (55%) | catalogued as rs1413467254, COSV100377336; called by muse, mutect2, varscan2
- ZNF74 | c.1548C>T p.I516= | Silent (SNP) | VAF 45/196 reads (23%) | catalogued as COSV62621051; called by muse, mutect2, varscan2
- ZNF804A | c.2658C>T p.L886= | Silent (SNP) | VAF 43/119 reads (36%) | catalogued as COSV100167100; called by muse, mutect2, varscan2
- ZNF862 | c.1419C>T p.F473= | Silent (SNP) | VAF 36/222 reads (16%) | catalogued as COSV99783332; called by muse, mutect2, varscan2
- A1CF | c.100-6662G>A | Intron (SNP) | VAF 39/80 reads (49%) | catalogued as COSV51025854; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840731 G>A | 5'Flank (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100005889; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846575 C>T | 5'Flank (SNP) | VAF 30/38 reads (79%) | called by muse, mutect2, varscan2
- DENND1A | c.1577+809C>T | Intron (SNP) | VAF 19/39 reads (49%) | catalogued as rs1247834754, COSV65337960; called by muse, mutect2, varscan2
- LAMA3 | c.4998+1484G>A | Intron (SNP) | VAF 52/186 reads (28%) | catalogued as COSV52530007; called by muse, mutect2, varscan2
- MIR889 | n.34C>T | RNA (SNP) | VAF 32/48 reads (67%) | called by muse, mutect2, varscan2
- NBPF11 | c.-549+2327C>T | Intron (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2, varscan2
- NDUFV3 | c.170-5551C>T | Intron (SNP) | VAF 108/172 reads (63%) | catalogued as COSV100446962; called by muse, mutect2, varscan2
- OR52A4P | n.988C>T | RNA (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2, varscan2
- RPL23AP42 | n.153A>T | RNA (SNP) | VAF 69/156 reads (44%) | called by muse, mutect2, varscan2
- SNORD115-14 | n.5C>T | RNA (SNP) | VAF 171/404 reads (42%) | catalogued as rs1211612409; called by muse, mutect2, varscan2
